Somatic mutation profile of tumor specimen MP2PRT-PAVYIV-TMP1-A (aliquot MP2PRT-PAVYIV-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAVYIV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (650 days).
Specimen MP2PRT-PAVYIV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8b9eed5-430a-418c-a4f2-900bc9e45759.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYIV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYIV-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20821d2d-d6f8-4c82-b999-78f7923048fc

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEFB118 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 28/560 reads (5%) | catalogued as rs34328728, COSV53620388; called by muse, mutect2
- ADAMTS5 | c.580A>C p.T194P | Missense Mutation (SNP) | VAF 59/754 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- CD80 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PHF14 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RP1 | c.1545C>G p.I515M | Missense Mutation (SNP) | VAF 15/397 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.146); called by muse, mutect2
- ADGRE3 | c.378C>T p.T126= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as rs1380763335; called by muse, mutect2
- DLX3 | c.831C>T p.P277= | Silent (SNP) | VAF 90/513 reads (18%) | catalogued as rs151274156, COSV71547589; called by muse, mutect2, varscan2
- SLC39A8 | c.720A>G p.E240= | Silent (SNP) | VAF 108/298 reads (36%) | catalogued as COSV63221848; called by muse, mutect2, varscan2
- OR7E19P | n.174G>A | RNA (SNP) | VAF 8/208 reads (4%) | catalogued as rs979788704; called by muse, mutect2
